Somatic mutation profile of tumor specimen 0DNMAU from CCDI case PBCBVS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.8 years (4,683 days).
Specimen 0DNMAU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30d6e745-22d6-4179-8a00-59ea851d4cbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a3d5f2c-ad81-4276-b8d7-4876a2c552ae

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MECP2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 116/459 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SKIV2L | c.2545A>G p.N849D | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MUC1 | c.438G>C p.P146= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs111364062; called by mutect2, varscan2
- SPAG9 | c.590+617del | Intron (DEL) | VAF 4/33 reads (12%) | called by mutect2, varscan2
